Gene-level copy-number profile of tumor specimen TCGA-L4-A4E5-01A from TCGA case TCGA-L4-A4E5, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 48.4 years (17,680 days).
Specimen TCGA-L4-A4E5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7906a02f-e96f-46d2-a1a5-9e35a9470234.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L4-A4E5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f59d25dd-10ca-4e22-a55c-b34e95cd952b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 24,606; copy number 2: 29,234; copy number 3: 3,154; copy number 4: 2,032; copy number 5: 722; copy number 6: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L4-A4E5-01A-11D-A24O-01): tumor purity 0.66, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:111,394,875–111,411,883, 2 genes: AC003989.2, AC003989.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 787 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,806,243–157,598,085, 22 genes, copy number 6: SH2D2A, NTRK1, INSRR, PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52, AL357143.1, AL357143.2, AL138900.1, LINC02772, AL138900.2, AL732406.1, AL353899.1, FCRL5, FCRL4.
- chr4:54,603,211–56,388,153, 42 genes, copy number 6: LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1.
- chr4:56,396,312–56,396,871, 1 gene, copy number 6: AC068620.2.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr8:78,268,637–79,314,951, 12 genes, copy number 5 (within-gene range 4–5): PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1.

Autosomal genes at a single copy (total copy number 1): 23,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
